Somatic mutation profile of tumor specimen C3N-01388-03 (aliquot CPT0088320009) from CPTAC case C3N-01388, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 53.2 years (19,447 days).
Specimen C3N-01388-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7c6ef01-f428-4e8a-bd10-67daa0d5f62b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01388-31 (Blood Derived Normal), aliquot CPT0088350002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec17c72a-87ba-4b23-bc8f-517fec5f6ed1

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, Nonsense Mutation 2, Frame Shift Del 1, 5'UTR 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 34/451 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- DOCK2 | c.3173A>C p.K1058T | Missense Mutation (SNP) | VAF 25/322 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56963361, COSV56971995; called by muse, mutect2
- GABRQ | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100941094; called by muse, mutect2
- HPS3 | c.2974C>T p.P992S | Missense Mutation (SNP) | VAF 16/231 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99224248; called by muse, mutect2
- HTR1E | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1222836067, COSV59508189, COSV59511573; called by muse, mutect2
- KIAA1217 | c.2669C>A p.S890Y | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV56814919, COSV56820494; called by muse, mutect2
- RBBP8NL | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as rs757950710; called by muse, mutect2
- SNX29 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as rs1416525578; called by muse, mutect2
- ARID1A | c.4545del p.S1516Lfs*11 | Frame Shift Del (DEL) | VAF 24/254 reads (9%) | called by mutect2, pindel
- CELF3 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- FAF1 | c.1181T>C p.M394T | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.408); called by muse, mutect2
- PARS2 | c.928A>C p.T310P | Missense Mutation (SNP) | VAF 11/289 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- RLIM | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 34/262 reads (13%) | called by muse, mutect2, varscan2
- SLC45A3 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 56/281 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TBC1D25 | c.1631T>C p.L544S | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.231); called by muse, mutect2
- TMEM102 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- USP49 | c.1794T>G p.Y598* | Nonsense Mutation (SNP) | VAF 45/615 reads (7%) | called by muse, mutect2
- ZNF91 | c.2887G>A p.E963K | Missense Mutation (SNP) | VAF 16/433 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.724); called by muse, mutect2
- FBRSL1 | c.2490C>T p.S830= | Silent (SNP) | VAF 14/135 reads (10%) | catalogued as rs780304489; called by muse, mutect2
- GNB5 | c.1092T>C p.F364= (on ENST00000261837 / NM_016194.4; = p.F322= on NM_006578.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/246 reads (10%) | called by muse, mutect2
- TAFA4 | c.177C>T p.H59= | Silent (SNP) | VAF 26/302 reads (9%) | called by muse, mutect2
- PLS3 | c.892-298C>T | Intron (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2
- SSTR5-AS1 | n.582G>A | RNA (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2
- ZNF346 | c.-22C>G | 5'UTR (SNP) | VAF 6/92 reads (7%) | catalogued as rs1386571072; called by muse, mutect2
